Somatic mutation profile of tumor specimen 0DLA1X from CCDI case PBBYVV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (868 days).
Specimen 0DLA1X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abf28f6c-14ef-4de0-b79a-a087ba00ed2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLA0Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0cc994b-0330-49e5-abad-b3937f12d6f4

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2C2 | c.162dup p.K55Qfs*39 | Frame Shift Ins (INS) | VAF 579/1678 reads (35%) | catalogued as rs1170087721; called by mutect2, pindel, varscan2
- MAP3K8 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 221/828 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs766981801; called by muse, mutect2, varscan2
- PRB2 | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 398/1104 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs1169356740, COSV66984135; called by mutect2, varscan2
- U2SURP | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 377/942 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL6A3 | c.7356C>T p.N2452= | Silent (SNP) | VAF 332/961 reads (35%) | catalogued as rs569662223, COSV55088626; called by muse, mutect2, varscan2
- NPR2 | c.219C>T p.G73= | Silent (SNP) | VAF 188/523 reads (36%) | catalogued as COSV100709300; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 40/1549 reads (3%) | called by muse, mutect2
- PROP1 | c.-40_-39del | 5'UTR (DEL) | VAF 27/131 reads (21%) | called by mutect2, pindel, varscan2
